Surgical pathology report (de-identified scan), TCGA case TCGA-34-5928, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-5928-01A (Primary Tumor).

[page 1 of 2]
PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Lung cancer

PROCEDURE: Lung lobectomy, thoracotomy.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

FINAL DIAGNOSIS:**Summary Statement**

The left lower lobe neoplasm is an invasive moderately differentiated squamous cell carcinoma measuring 3.7 cm. Visceral pleural invasion is identified. Angiolymphatic invasion is identified. One N1 lymph node is involved by metastatic squamous cell carcinoma. All the margins of resection are free of tumor. The stage is T2 N1 MX.

PART 1: LYMPH NODE, LEFT LEVEL 9, BIOPSY –
ONE (1) REACTIVE LYMPH NODE. NO TUMOR SEEN.

PART 2: LYMPH NODES, LEFT LEVEL 10 NEAR INFERIOR PULMONARY VEIN, BIOPSY –
THREE (3) REACTIVE LYMPH NODES WITH FOCAL NECROTIZING GRANULOMAS AND CALCIFICATIONS. NO TUMOR SEEN.

PART 3: LYMPH NODE, LEFT LEVEL 11 NEAR PULMONARY ARTERY, BIOPSY –
ONE (1) REACTIVE LYMPH NODE WITH NECROTIZING GRANULOMAS AND CALCIFICATIONS. NO TUMOR SEEN.

PART 4: LYMPH NODE, LEVEL 5, BIOPSY –
ONE (1) REACTIVE LYMPH NODE. NO TUMOR SEEN.

PART 5: LYMPH NODES, LEVEL 6, BIOPSY –
TWO (2) REACTIVE LYMPH NODES. NO TUMOR SEEN.

PART 6: LYMPH NODE, LEFT LEVEL 10, BIOPSY –
ONE (1) REACTIVE LYMPH NODE WITH NECROTIZING GRANULOMAS AND CALCIFICATIONS. NO TUMOR SEEN.

PART 7: LUNG, LEFT LOWER LOBE, LOBECTOMY

- A. INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA WITH FOCAL BASALOID AREAS (3.7 CM).
- B. ANGIOLYMPHATIC INVASION IDENTIFIED.
- C. VISCERAL PLEURAL INVASION IDENTIFIED.
- D. MARGINS OF RESECTION FREE OF TUMOR.
- E. METASTATIC SQUAMOUS CELL CARCINOMA INVOLVING ONE (1) OF SIX (6) PERIBRONCHIAL LYMPH NODES.
- F. CALCIFIED AND FIBROTIC GRANULOMA (1.0 CM).
- G. ANTHRACOTIC AND FIBROTIC NODULE (0.2 CM).
- H. BACKGROUND LUNG SHOWING EMPHYSEMA, PERIBRONCHIOLAR METAPLASIA, ALVEOLAR EDEMA, BRONCHIECTASIS, BRONCHIOLOECTASIS, AND PULMONARY HYPERPLASTIC ARTERIOPATHY.
- I. STAGE: T2 N1 MX.

PART 8: LYMPH NODE, LEVEL 12, BIOPSY –
TWO REACTIVE LYMPH NODES. NO TUMOR SEEN.

PART 9: LYMPH NODE, BRONCHIAL LYMPH NODE NEAR LEFT LOWER BRONCHUS, BIOPSY –
ONE LYMPH NODE WITH NECROTIZING GRANULOMA AND CALCIFICATIONS. NO TUMOR SEEN.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY LUNG TUMORS**

TUMOR LOCATION:	Left Lower Lobe
PROCEDURE:	Lobectomy
TUMOR SIZE:	Maximum dimension: 3.7 cm
GROSS SATELLITES:	Number of gross satellite lesions: 0
TUMOR TYPE:	Invasive squamous carcinoma
HISTOLOGIC GRADE:	G2, Moderately differentiated
MICROSCOPIC SATELLITES:	Number of microscopic satellite lesions: 0
EXTRAPULMONARY PARENCHYMAL EXTENSION/INVASION OF TUMOR:	Visceral pleura
ANGIOLYMPHATIC INVASION:	Yes
TUMOR NECROSIS:	< or = to 50%
SURGICAL MARGIN INVOLVEMENT:	No
INFLAMMATORY(DESMOPLASTIC) REACTION:	Mild
N1 LYMPH NODES:	Number of N1 lymph nodes positive: 1 Number of N1 lymph nodes examined: 14
N2 LYMPH NODES:	Number of N2 lymph nodes positive: 0 Number of N2 lymph nodes examined: 4
UNDERLYING DISEASE(S):	Bronchiectasis, Emphysema
T STAGE, PATHOLOGIC:	pT2

[page 2 of 2]
ADDENDA:

Addendum

PROBE: LSI EGFR/CEP7

EGFR FISH STUDIES PERFORMED ON THE SQUAMOUS CELL CARCINOMA ARE POSITIVE BY COLORADO CRITERIA.

Number of cells analyzed: 60
Ratio EGFR/CEP7: 1.18
SNR (signal to nucleus ratio): 2.0
Hyperdiploid rate for CEP 7: 8.3%
≥ 4 copies of the EGFR signal: 5(8.3%)
Small gene cluster (4-10 copies): 0(0%)
Larger and brighter EGFR signals than CEP7 signals: 11(18.3%)
>15 copies of EGFR signals: 0(0%)

PROBE: LSI ALK Dual-Color Break-apart Probe 2p23

ALK FISH STUDIES PERFORMED ON THE SQUAMOUS CELL CARCINOMA ARE NEGATIVE.

Number of cells analyzed: 60
% of cells positive for the ALK rearrangement: 0%
Only split O & G (single O and single G in the same nucleus): 0%
Fusion + split O and G in the same nucleus: 0%
Only single O: 0%
Fusion + single O: 0%

% of the cells with the normal pattern: 60(100%)

EGFR FISH analysis was manually performed and quantitatively assessed by analysis of a minimum of 60 cells using the EGFR SpectrumOrange and the CEP7 SpectrumGreen probes.

ALK FISH analysis was manually performed and quantitatively assessed by analysis of a minimum of 60 cells using the ALK SpectrumOrange (telomeric) and the ALK SpectrumGreen (centromeric) probes.

UCCC criteria for stratification of NSCLC patients:

EGFR FISH positive:

- 1) EGFR gene amplification defined as one of the following:
- a) EGFR gene to CEP7 ratio ≥ 2
- b) Small gene cluster (4-10 copies) or innumerable tight gene cluster in > 10% of tumor cells
- c) Larger and brighter EGFR signals than CEP7 signals in > 10% of tumor cells, while EGFR signals are smaller than the CEP7 signals in the adjacent stromal and reactive cells
- d) >15 copies of the EGFR signals in > 10% of tumor cells or
- 2) Specimens with > 40% of cells displaying > 4 copies of the EGFR signal.

EGFR FISH negative:

Specimens without gene amplification as defined above and with $\leq 40\%$ of cells displaying ≥ 4 copies of the EGFR signal.

Clinical studies show high EGFR gene copy number by FISH analysis to be associated with favorable clinical benefit (clinical response, stable disease, time to progression, and survival) in patients with advanced non-small cell lung cancer treated with EGFR tyrosine kinase inhibitors.

ALK translocation is detected as follows:

ALK negative:

0-15% of cells positive for the ALK rearrangement.

Normal cells without the ALK translocation show green and orange signals in juxtaposition.

ALK positive:

Greater than 15% of cells positive for the ALK rearrangement.

Cells with the ALK translocation show one of the following patterns: One pair of signals (green and orange) fused or in juxtaposition and one green and one orange signal separated; Only split O & G (single O and single G in the same nucleus); Only single O; Fusion + single O.

Addendum

The granulomas in the left lower lobe lung specimen (Part 7) and left lower lobe bronchial lymph node (Part 9) show small fungal yeast forms on the Grocott stain that are negative on the mucicarmine stains. These fungal forms most likely represent Histoplasma species. Clinical correlation is suggested. AFB stains are negative.

Source: NCI Genomic Data Commons file bf1f44a7-2791-4fdb-901f-85febd848167 (TCGA-34-5928.0880181A-6D0E-4B59-82B3-46A4F44F49B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).